Somatic mutation profile of tumor specimen TCGA-XE-AAOC-01A (aliquot TCGA-XE-AAOC-01A-11D-A435-10) from TCGA case TCGA-XE-AAOC, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Teratoma, malignant, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 31.7 years (11,566 days).
Specimen TCGA-XE-AAOC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d72e6fb-d5a1-4b51-ba7f-6efc73d1645f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-AAOC-10A (Blood Derived Normal), aliquot TCGA-XE-AAOC-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7674b68b-19da-43f1-82fb-0301e64f1184

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 13, Silent 7, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF2D | c.399_400del p.A134Hfs*21 | Frame Shift Del (DEL) | VAF 146/800 reads (18%) | catalogued as rs1553413095; called by pindel, varscan2
- HSP90B1 | c.1008G>A p.M336I | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV55357356; called by muse, mutect2
- KDM5A | c.2005G>A p.V669I | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs757217718, COSV66992273; called by muse, mutect2, varscan2
- PLCL1 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.05); catalogued as rs201197388; called by muse, mutect2, varscan2
- POU4F3 | c.245C>A p.T82N | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as rs145218099; called by muse, mutect2, varscan2
- PRR14L | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as rs1445051708; called by muse, mutect2, varscan2
- TAF1L | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 114/358 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54258011; called by muse, mutect2, varscan2
- ARPC2 | c.401A>C p.E134A | Missense Mutation (SNP) | VAF 83/287 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARSB | c.776A>G p.Q259R | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CEP128 | c.2510C>T p.A837V | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ESCO1 | c.1205_1206del p.V402Afs*4 | Frame Shift Del (DEL) | VAF 14/133 reads (11%) | called by pindel, varscan2
- KDM5B | c.2945+1G>T p.X982_splice | Splice Site (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- MED23 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 70/104 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RANBP10 | c.1466C>A p.S489Y | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- SIGLEC1 | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLIT3 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- BAZ1B | c.3753T>C p.S1251= | Silent (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- CDC42BPA | c.831C>T p.Y277= | Silent (SNP) | VAF 65/256 reads (25%) | catalogued as rs139987030; called by muse, mutect2, varscan2
- DCC | c.147C>T p.A49= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs777555256, COSV59122660; called by muse, mutect2, varscan2
- H3C8 | c.87C>T p.S29= | Silent (SNP) | VAF 47/85 reads (55%) | catalogued as rs760606364; called by muse, mutect2, varscan2
- IL4R | c.199C>T p.L67= | Silent (SNP) | VAF 8/149 reads (5%) | called by muse, mutect2
- KIF16B | c.1756C>T p.L586= | Silent (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- PCK1 | c.558T>C p.D186= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as rs201469307; called by muse, mutect2, varscan2
